Somatic mutation profile of tumor specimen TARGET-20-PARIEG-04A (aliquot TARGET-20-PARIEG-04A-01D) from TARGET case TARGET-20-PARIEG, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 13.4 years (4,881 days).
Specimen TARGET-20-PARIEG-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe6fa7b8-1a98-49fe-b96b-2fbbe25e7791.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARIEG-14A (Bone Marrow Normal), aliquot TARGET-20-PARIEG-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/69df12c3-05c3-43a2-88c1-56279ea859c9

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 8, Silent 3, Nonsense Mutation 2, In Frame Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ETV6 | c.195_196insTCA p.D65_V66insS | In Frame Ins (INS) | VAF 24/70 reads (34%) | catalogued as COSV67148584; called by pindel, varscan2
- FAXDC2 | c.340C>T p.R114* | Nonsense Mutation (SNP) | VAF 79/156 reads (51%) | catalogued as rs769797713, COSV58172365; called by muse, mutect2, varscan2
- FGF5 | c.63C>A p.H21Q | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as COSV100427898; called by muse, mutect2, varscan2
- GATA2 | c.1114G>A p.A372T | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM141458, COSV62002954; called by muse, mutect2, varscan2
- IQCA1 | c.205C>T p.R69* | Nonsense Mutation (SNP) | VAF 62/133 reads (47%) | catalogued as rs901228069, COSV54502587; called by muse, mutect2, varscan2
- PLEKHG3 | c.860T>A p.I287N (on ENST00000394691; = p.I343N on NM_001308147.2) | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV99906847; called by muse, mutect2, varscan2
- RYR3 | c.5530C>T p.R1844C | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754927860, COSV101212508, COSV66778915; called by muse, mutect2, varscan2
- SYNE1 | c.8586A>C p.E2862D (on ENST00000367255 / NM_182961.4; = p.E2869D on NM_033071.3) | Missense Mutation (SNP) | VAF 179/397 reads (45%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV55071049; called by muse, mutect2, varscan2
- ETV6 | c.328+1_328+3del p.X110_splice | Splice Site (DEL) | VAF 37/83 reads (45%) | called by pindel, varscan2
- HTR3E | c.583G>A p.E195K (on ENST00000415389 / NM_001256613.1; = p.E210K on NM_182589.2) | Missense Mutation (SNP) | VAF 65/143 reads (45%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- MYO5C | c.4810A>G p.M1604V | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); called by muse, varscan2
- NBEA | c.6506G>T p.G2169V | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CES4A | c.750G>A p.A250= | Silent (SNP) | VAF 85/193 reads (44%) | catalogued as rs781591841; called by muse, mutect2, varscan2
- LIPN | c.1038C>T p.L346= | Silent (SNP) | VAF 141/284 reads (50%) | catalogued as rs771416939, COSV101356201, COSV101356239; called by muse, mutect2, varscan2
- RAPH1 | c.795G>A p.E265= (on ENST00000319170 / NM_213589.3; = p.E317= on NM_203365.4) | Silent (SNP) | VAF 266/598 reads (44%) | catalogued as COSV57357143; called by muse, mutect2, varscan2
